Gene-level copy-number profile of tumor specimen ALCH-AFFN-TTP1-A from ALCHEMIST case ALCH-AFFN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,227 days).
Specimen ALCH-AFFN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f7196388-2dd6-4e64-95a7-a121a470fb19.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFFN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/8962655e-5f07-4432-b43d-bda347b3d33e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,285; copy number 2: 33,648; copy number 3: 15,793; copy number 4: 5,707; copy number 5: 438; copy number 6: 698; copy number 7: 444; copy number 8: 83; copy number 11: 10; copy number 12: 188; copy number 13: 1; copy number 16: 58; copy number 17: 31; copy number 20: 13.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,128,107–12,139,077, 3 genes (within-gene range 0–1): AC130366.1, USP17L7, USP17L2.
- chr21:13,968,489–13,968,595, 1 gene (within-gene range 0–1): RNU6-954P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,964 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:109,879,070–110,615,458, 16 genes, copy number 5: KRT19P3, EGF, RNU6-35P, ELOVL6, RN7SL275P, AC093770.1, HSBP1P2, RNF14P2, RNU6-205P, ZBED1P1, ENPEP, RPL7L1P13, ZNF969P, AC093872.1, AC098798.1, PANCR.
- chr6:85,387,219–85,678,932, 11 genes, copy number 5: LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2, SNX14, AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B.
- chr6:85,868,953–85,998,263, 3 genes, copy number 5: AL450338.1, AL450338.2, RNU4-12P.
- chr6:159,094,093–159,170,007, 2 genes, copy number 5 (within-gene range 2–5): AL356417.1, AL356417.2.
- chr6:165,279,664–166,113,273, 10 genes, copy number 6: C6orf118, PDE10A, RNA5SP226, RNU6-730P, AL590302.2, AL590302.1, LINC00602, GAPDHP72, AL627443.1, AL627443.2.
- chr6:168,441,151–168,820,656, 3 genes, copy number 5: SMOC2, AL136099.1, AL513210.2.
- chr6:169,419,969–169,702,047, 1 gene, copy number 5 (within-gene range 2–5): AL031315.1.
- chr6:169,457,212–170,419,325, 22 genes, copy number 5: WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1.
- chr7:14,145,049–14,974,777, 1 gene, copy number 5 (within-gene range 4–5): DGKB.
- chr7:14,814,131–20,590,085, 71 genes, copy number 5–7 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 6: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 6: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 6 (within-gene range 4–6): TRGV5P, TRGV5.
- chr8:35,235,475–35,796,550, 1 gene, copy number 16 (within-gene range 2–16): UNC5D.
- chr8:35,525,176–39,417,378, 87 genes, copy number 7–16 (broad region; genes not listed).
- chr8:39,522,976–103,501,895, 1,008 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:137,424,904–141,518,737, 47 genes, copy number 6–7: ZYXP1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1.
- chr11:86,244,753–86,345,943, 6 genes, copy number 5: EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P.
- chr11:93,661,682–93,850,618, 21 genes, copy number 5: CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA.
- chr11:96,352,769–96,389,956, 1 gene, copy number 6: CCDC82.
- chr14:22,040,594–22,499,749, 62 genes, copy number 5–6 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.
- chr14:29,940,745–53,991,995, 378 genes, copy number 6–20 (within-gene range 4–20) (broad region; genes not listed).
- chr17:26,981,694–28,897,733, 118 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:21,488,244–23,826,729, 67 genes, copy number 5–8 (broad region; genes not listed).
- chr20:35,615,829–35,753,719, 10 genes, copy number 5: SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1.

Autosomal genes at a single copy (total copy number 1): 1,105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
